Surgical pathology report (de-identified scan), TCGA case TCGA-BI-A0VR, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-BI-A0VR-01A (Primary Tumor).

[page 1 of 2]
FINAL DIAGNOSIS:

PART 1: OVARY AND FALLOPIAN TUBE, LEFT SALPINGO-OOPHORECTOMY -

- A. OVARY WITH EPITHELIAL INCLUSIONS, NO TUMOR SEEN.
- B. FALLOPIAN TUBE, NO TUMOR SEEN.

PART 2: LYMPH NODES, LEFT PELVIC, BIOPSY - TWO LYMPH NODES, FREE OF TUMOR (0/2).

PART 3: LYMPH NODES, LEFT OBTURATOR, BIOPSY - THIRTEEN LYMPH NODES, FREE OF TUMOR (0/13).

PART 4: LYMPH NODES, RIGHT PELVIC, BIOPSY - TWO LYMPH NODES, FREE OF TUMOR (0/2).

PART 5: LYMPH NODE, RIGHT OBTURATOR, BIOPSY - ONE LYMPH NODE, FREE OF TUMOR (0/1).

PART 6: BROAD LIGAMENT, RIGHT, BIOPSY - FIBROVASCULAR ADIPOSE TISSUE, NO TUMOR SEEN.

PART 7: LYMPH NODES, LEFT PERIAORTIC, BIOPSY - TEN LYMPH NODES, FREE OF TUMOR (0/10).

PART 8: LYMPH NODES, RIGHT PERIAORTIC, BIOPSY - THREE LYMPH NODES, FREE OF TUMOR (0/3).

PART 9: LYMPH NODES, RIGHT COMMON, BIOPSY - TWO LYMPH NODES, FREE OF TUMOR (0/2).

PART 10: UTERUS WITH BOTH PERIMETRIA, RADICAL HYSTERECTOMY (92 GRAMS) -

- A. UTERINE CERVIX WITH INVASIVE SQUAMOUS CELL CARCINOMA (10A-10E, 10G AND 10P), HIGH NUCLEAR GRADE (3/3), WITH LYMPHOVASCULAR PERMEATION. 2.5 X 1.8 X 1.5 CM. THE TUMOR ARISES IN A BACKGROUND OF CERVICAL INTRAEPITHELIAL NEOPLASIA 3, EXTENDS FROM 3 O'CLOCK TO 9 O'CLOCK AND INVOLVES THE POSTERIOR CERVIX. THE TUMOR COMES TO WITHIN 1.5 MM FROM THE NEAREST POSTERIOR RESECTION MARGIN (AT THE 6 O'CLOCK POSITION -10A).
- B. CHRONIC CYSTIC CERVICITIS.
- C. CHANGES CONSISTENT WITH PREVIOUS BIOPSY SITE, SEE PRIOR [REDACTED]
- D. PROLIFERATIVE PATTERN ENDOMETRIUM WITH CYSTIC CHANGES.
- E. ENDOMETRIAL POLYP WITH CYSTIC CHANGES.
- F. LEIOMYOMA, UP TO 0.5 CM.
- G. LEFT PERIMETRIA WITH MICROMETASTATIC SQUAMOUS CELL CARCINOMA, INVOLVING ONE (1/7) LYMPH NODES (10K) (see comment).
- H. RIGHT PERIMETRIA INVOLVED BY METASTATIC SQUAMOUS CELL CARCINOMA (10P) AND TWO REACTIVE LYMPH NODES (0/2) (see comment).
- I. VAGINAL CUFF, FREE OF TUMOR.
- J. PORTION OF LEFT FALLOPIAN TUBE, FREE OF TUMOR.

1CD-0-3

Carcinoma, Squamous cell 8070/3

Site: cervix, NOS C53.9

lw
11/27/11

COMMENT:

The left perimetrial lymph node is involved with tumor which measures up to 0.3 mm on the slide (10K). This lymph node is present in the outer third of the perimetrium. The metastatic tumor in the right perimetrium is present in the outer third of the perimetrium.

[page 2 of 2]
PATIENT HISTORY:

Not given. Date of last menstrual period: Not given.

PRE OP DIAGNOSIS: Cervical cancer.

POST OP DIAGNOSIS: Same.

PROCEDURE: Radical hysterectomy, left salpingo-oophorectomy and lymph node biopsies.

CASE SYNOPSIS:**SYNOPTIC - PRIMARY UTERINE CERVIX TUMORS: HYSTERECTOMY AND CONIZATION****TUMOR TYPE:**

Squamous cell carcinoma

Squamous intraepithelial lesion (SIL)

HISTOLOGIC GRADE:

Poorly differentiated

High grade squamous intraepithelial lesion (HSIL)

TUMOR SIZE:

Maximum dimension: 2.5 cm

TUMOR LOCATION:

Endocervix

DEPTH OF INVASION:

2/3 of cervical thickness

TUMOR THICKNESS:

Tumor thickness: 15 mm

HORIZONTAL SPREAD:

Horizontal Spread: 2.5 cm.

STRUCTURES INVOLVED:

Parametrium

NON-NEOPLASTIC UTERUS:

Leiomyoma

MARGINS OF RESECTION:

Vaginal margin is negative for tumor

Parametrium margin is positive for tumor

MITOTIC RATE:

Mitotic rate: 100 / 10 HPF

ANGIOLYMPHATIC INVASION:

Angiolymphatic invasion present

LYMPH NODES POSITIVE:

Number of lymph nodes positive: 1

LYMPH NODES EXAMINED:

Total number of lymph nodes examined: 42

LYMPH NODE GROUPS INVOLVED:

Parametrial lymph nodes, Left

EXTRANODAL EXTENSION:

No

T STAGE, PATHOLOGIC:

pT2b

N STAGE, PATHOLOGIC:

pN1

M STAGE, PATHOLOGIC:

pMX

FIGO STAGE:

IIB

RESIDUAL TUMOR:

Rx

Disagnosis Discrepancy		

KN

Source: NCI Genomic Data Commons file 9da99af6-7341-4eee-a610-c32c30b8e720 (TCGA-BI-A0VR.BA4A1AA9-C1C7-4F84-A375-02B51FB95494.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).